Somatic mutation profile of tumor specimen 0DG38B from CCDI case PBBREH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Central neurocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,343 days).
Specimen 0DG38B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4a09886-daec-4401-8143-9195892f81a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG384 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b12f12f-140b-41e8-a4b9-ddf502739bb5

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BX276092.9 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1031595281; called by muse, mutect2
- HEATR1 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 143/421 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1450604396; called by muse, mutect2, varscan2
- HECW1 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as rs1562986148, COSV67828342; called by muse, mutect2
- PRC1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.379); catalogued as rs146881444; called by muse, mutect2, varscan2
- TEX13D | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 20/431 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs1364180197, COSV69794684; called by muse, mutect2
- TEX13D | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV69794686; called by muse, mutect2
- CCDC88B | c.676-94C>T | Intron (SNP) | VAF 16/132 reads (12%) | catalogued as rs778974800; called by muse, varscan2
- PDHA1 | c.*2000C>G | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
